TCGA case TCGA-EK-A2RB — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f92a994d-b080-42c9-966f-34c1000865e3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 48.6 years (17,752 days); Year of diagnosis: 2011; Method of diagnosis: Biopsy; FIGO stage: Stage IVB; FIGO staging edition year: 1988; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.

Follow-up (3 entries)
- Day 0 (postoperative): ECOG performance status: 0.
- Day 2 (postoperative): ECOG performance status: 0.
- Days to follow up: 9 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 175 cm; BMI: 34.3.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EK-A2RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 70 mg.
  Slide TCGA-EK-A2RB-01A-01-TS1: Section location: Top; Percent tumor cells: 84; Percent tumor nuclei: 92; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 15; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EK-A2RB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Performance status other timing: post-op; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Cervical biopsies and cystoscopy; Lymph nodes examined: No.
- Follow-up form: Lost to follow-up: Yes; Performance status other timing: post-op; Days from index date to performance status: 2.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 9 days; disease-specific survival: no event (censored), 9 days; progression-free interval: no event (censored), 9 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EK-A2RB-01A-11D-A18H-01): tumor purity 0.81, ploidy 2.03, whole-genome doublings 0.
